Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A905, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A905-01A (Primary Tumor).

Name: [REDACTED]
Address: [REDACTED]

Surg. Path. No.: [REDACTED]
DOB: [REDACTED] Age: [REDACTED]
Sex/Race: F UNKNOWN
Service: [REDACTED]
Date Received: [REDACTED]

[REDACTED] M.D.

[REDACTED]

ICD-O-3
Carcinoma, squamous cell NOS
Site Cervix NOS
C53.9
JW 1/21/14

DIAGNOSIS

UTERUS, CERVIX, BIOPSY - SQUAMOUS CELL CARCINOMA, MODERATELY
DIFFERENTIATED, INVASIVE

UTERUS, ENDOCERVIX, CURETTAGE - SQUAMOUS CELL CARCINOMA, MODERATELY
DIFFERENTIATED, INVASIVE

HISTORY

The patient is a [REDACTED] year old woman with a cervical lesion and
severe dysplasia by cytology. Clinical diagnosis: Same. Operative
procedure: Colposcopy with the finding of a friable, ulcerated
lesion on the cervix.

GROSS

Submitted for review by [REDACTED] are 2 slides, labelled
[REDACTED] accompanied by a corresponding pathology report. The
material originates from [REDACTED]
Two slides are retained for our files.

COMMENT

Microscopic examination substantiates the above cited diagnosis.

--1--

Criteria	W 12/15/13	Yes	No

Source: NCI Genomic Data Commons file 3ed7b205-564e-4101-8614-c43a64aa8a74 (TCGA-C5-A905.A2899C0E-696C-4613-8443-35FDC795CD01.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).